Somatic mutation profile of tumor specimen TCGA-IB-7644-01A (aliquot TCGA-IB-7644-01A-11D-2154-08) from TCGA case TCGA-IB-7644, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 65.8 years (24,043 days).
Specimen TCGA-IB-7644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8286804-1ba2-4a26-96f6-93cc6a74590e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7644-10A (Blood Derived Normal), aliquot TCGA-IB-7644-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f47d1b0-7752-4ee4-8654-891e883c20e6

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 23, Silent 5, Splice Region 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 128/300 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRF4 | c.1171A>T p.M391L | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99349057; called by muse, mutect2, varscan2
- ADNP | c.521A>T p.D174V | Missense Mutation (SNP) | VAF 289/937 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100823866; called by muse, mutect2, varscan2
- CELSR3 | c.8351C>T p.P2784L | Missense Mutation (SNP) | VAF 116/349 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99375065; called by muse, mutect2, varscan2
- CENPJ | c.1531G>T p.D511Y | Missense Mutation (SNP) | VAF 199/614 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV101121582, COSV67884111; called by muse, mutect2, varscan2
- FLRT2 | c.1624C>A p.L542M | Missense Mutation (SNP) | VAF 237/743 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.921); catalogued as COSV100421067, COSV58141203; called by muse, mutect2, varscan2
- LAMB2 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 131/415 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs544982873, COSV59731554; called by muse, mutect2, varscan2
- MYO9A | c.2638C>G p.H880D | Missense Mutation (SNP) | VAF 102/261 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100614365; called by muse, mutect2, varscan2
- PCDHA4 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 184/539 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs13189658, COSV63539039; called by muse, mutect2, varscan2
- PCDHGB6 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs1447189643, COSV99547463; called by muse, mutect2, varscan2
- PDZRN3 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 112/389 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375528245; called by muse, mutect2, varscan2
- PRPS1 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 46/872 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100978894; called by muse, mutect2
- SERPINB5 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 97/193 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV101237698; called by muse, mutect2, varscan2
- SLCO1B3 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99682288; called by muse, mutect2
- SMAD4 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV61685296, COSV61696805; called by muse, mutect2, varscan2
- SPARC | c.732C>T p.D244= | Splice Region (SNP) | VAF 68/326 reads (21%) | catalogued as rs758034123, COSV50557814; called by muse, mutect2, varscan2
- SYNJ2 | c.1853C>G p.S618C | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100840669; called by muse, mutect2, varscan2
- TACC2 | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV100554042; called by muse, mutect2, varscan2
- TRIM73 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 112/581 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99303109; called by muse, mutect2, varscan2
- UGGT2 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 188/604 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs745325927, COSV100942673; called by muse, mutect2, varscan2
- VPS29 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 112/402 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100804921; called by muse, mutect2, varscan2
- WNT7B | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs956976713, COSV100254783; called by muse, mutect2, varscan2
- WTAP | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs112093927, COSV100493427; called by muse, mutect2, varscan2
- FAM8A1 | c.941_946del p.L314_V315del | In Frame Del (DEL) | VAF 87/313 reads (28%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 131/557 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CACNA1A | c.1137G>A p.L379= | Silent (SNP) | VAF 141/442 reads (32%) | catalogued as COSV100803273; called by muse, mutect2, varscan2
- IGFALS | c.370C>T p.L124= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99236702; called by muse, varscan2
- OPCML | c.618C>T p.N206= | Silent (SNP) | VAF 122/376 reads (32%) | catalogued as rs143650226, COSV59403540; called by muse, mutect2, varscan2
- SLCO1C1 | c.264T>C p.F88= | Silent (SNP) | VAF 188/523 reads (36%) | catalogued as COSV99860067; called by muse, mutect2, varscan2
- SPTBN4 | c.5646T>C p.H1882= | Silent (SNP) | VAF 144/445 reads (32%) | catalogued as rs753871831, COSV100152183; called by muse, mutect2, varscan2
